Somatic mutation profile of tumor specimen ALCH-B1N9-TTP1-A (aliquot ALCH-B1N9-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1N9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.9 years (22,966 days).
Specimen ALCH-B1N9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9d87d55-222d-4672-8b8b-c4c646819814.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1N9-NB1-A (Blood Derived Normal), aliquot ALCH-B1N9-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6378ab8-2d52-408b-87df-46f8af2df387

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 7, Frame Shift Del 6, 3'UTR 2, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOX1 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 37/337 reads (11%) | catalogued as rs961341488, COSV101021674; called by muse, mutect2, varscan2
- CCL13 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187454526, COSV99861674; called by muse, mutect2, varscan2
- DNAH17 | c.4447G>T p.D1483Y | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67750391; called by muse, mutect2
- HES6 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99800623; called by muse, mutect2, varscan2
- LAMC2 | c.2510C>T p.A837V | Missense Mutation (SNP) | VAF 56/516 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs373907823, COSV99917264; called by muse, mutect2, varscan2
- OPA1 | c.1700T>C p.I567T (on ENST00000361510 / NM_130837.3; = p.I512T on NM_015560.3) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs148834015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OTOA | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 75/467 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.736); catalogued as rs777388246, COSV53756812; called by muse, mutect2, varscan2
- RBM10 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.04); catalogued as CS1414400, COSV61311565; called by muse, mutect2, varscan2
- SLC13A4 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404995282, COSV62461333; called by muse, mutect2, varscan2
- TENM1 | c.4555C>T p.R1519C | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64431715; called by muse, mutect2, varscan2
- TGFB1 | c.29_31del p.P10del | In Frame Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs779901179; called by mutect2, pindel
- TGFBR3 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 42/239 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs939563832, COSV53031840; called by muse, mutect2, varscan2
- UBE2E3 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as rs772827469, COSV66583894; called by muse, mutect2, varscan2
- ALOX12 | c.1384C>G p.H462D | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ATN1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BSPH1 | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CFAP74 | c.822C>G p.C274W | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CMYA5 | c.1646C>A p.P549Q | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- COX10 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EPHB6 | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GLI2 | c.2755G>A p.G919R (on ENST00000361492 / NM_001374353.1; = p.G936R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ITGB6 | c.29_32del p.F10Yfs*3 | Frame Shift Del (DEL) | VAF 42/179 reads (23%) | called by pindel, varscan2
- MACF1 | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 43/258 reads (17%) | called by muse, mutect2, varscan2
- MUL1 | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.224); called by muse, mutect2
- NUP88 | c.1410del p.W470* | Frame Shift Del (DEL) | VAF 35/250 reads (14%) | called by mutect2, pindel, varscan2
- PCDH11X | c.908A>T p.N303I | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RAG1 | c.2596_2603del p.V866Sfs*3 | Frame Shift Del (DEL) | VAF 65/331 reads (20%) | called by mutect2, pindel, varscan2
- RIOK1 | c.1102T>G p.F368V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAXO1 | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SLC9A9 | c.83A>T p.N28I | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SNX29 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TENM1 | c.3533G>A p.R1178K | Missense Mutation (SNP) | VAF 63/499 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TMC2 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMF1 | c.1793_1794del p.K598Rfs*14 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- TMPRSS15 | c.916A>T p.I306F | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TTLL5 | c.2080del p.D694Tfs*37 | Frame Shift Del (DEL) | VAF 55/519 reads (11%) | called by mutect2, pindel, varscan2
- USP9X | c.2069_2073del p.Y690Lfs*2 | Frame Shift Del (DEL) | VAF 29/178 reads (16%) | called by mutect2, pindel, varscan2
- ZNF839 | c.904T>G p.L302V (on ENST00000558850 / NM_001267827.1; = p.L418V on NM_018335.5) | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KIRREL2 | c.390C>A p.G130= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs144138799; called by muse, mutect2, varscan2
- NME9 | c.720C>T p.D240= (on ENST00000333911 / NM_001349024.2; = p.D179= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/338 reads (12%) | catalogued as rs377196410; called by muse, mutect2, varscan2
- PSAPL1 | c.969C>T p.R323= | Silent (SNP) | VAF 41/253 reads (16%) | catalogued as rs370464084; called by muse, mutect2, varscan2
- ROBO3 | c.1962C>T p.P654= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs1022999467; called by muse, mutect2, varscan2
- THSD4 | c.678A>G p.Q226= | Silent (SNP) | VAF 51/319 reads (16%) | called by muse, mutect2, varscan2
- TRPM5 | c.666G>A p.E222= | Silent (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2, varscan2
- UMOD | c.837C>T p.P279= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs753578904, COSV56773241; called by muse, mutect2, varscan2
- FGD6 | c.*32A>G | 3'UTR (SNP) | VAF 10/44 reads (23%) | catalogued as rs1221254203, COSV100676274; called by muse, mutect2
- TRMT61A | c.*490G>C | 3'UTR (SNP) | VAF 4/73 reads (5%) | called by muse, mutect2
